Somatic mutation profile of tumor specimen ALCH-ABD5-TTR1-A (aliquot ALCH-ABD5-TTR1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-ABD5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,000 days).
Specimen ALCH-ABD5-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed31e76-18ca-47b0-98f8-270da9b571e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABD5-NB1-A (Blood Derived Normal), aliquot ALCH-ABD5-NB1-A-1-0-D-A485-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3d08348-a0ed-499f-a041-61436ff2b8d2

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Intron 3, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.4392+1G>A p.X1464_splice (on ENST00000341947 / NM_080680.3; = p.X1357_splice on NM_080679.2) | Splice Site (SNP) | VAF 10/176 reads (6%) | catalogued as rs750995470, CS951381, COSV59499666; ClinVar: pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1821/2557 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BCHE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100012006; called by muse, mutect2
- CDH10 | c.1125A>G p.I375M | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1274114970; called by muse, mutect2
- FOXN4 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 66/819 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753454851; called by muse, mutect2
- HLA-C | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.982); catalogued as rs752664590; called by muse, mutect2, varscan2
- LARGE2 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs891485767; called by muse, mutect2
- MED13 | c.790T>G p.L264V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1175333247; called by muse, mutect2
- N4BP3 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as COSV99200670; called by muse, mutect2, varscan2
- NCKAP5 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs747116383; called by muse, mutect2, varscan2
- NLRP12 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 25/372 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759770066; called by muse, mutect2
- PLEC | c.5195C>T p.S1732F (on ENST00000322810 / NM_201380.4; = p.S1622F on NM_000445.5) | Missense Mutation (SNP) | VAF 28/463 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1206944270; called by muse, mutect2
- RBM10 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | catalogued as COSV61308434; called by muse, mutect2, varscan2
- SCRIB | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782386048; called by muse, mutect2, varscan2
- TMEM87A | c.684+2T>A p.X228_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | catalogued as COSV67746903; called by muse, mutect2
- ASPM | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 84/954 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2
- ATAD5 | c.3526C>T p.Q1176* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ATM | c.2420_2433del p.L807Yfs*3 | Frame Shift Del (DEL) | VAF 58/353 reads (16%) | called by mutect2, pindel
- C1QTNF2 | c.262G>A p.G88S (on ENST00000393975; = p.G43S on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CABIN1 | c.2511_2515delinsA p.K838Sfs*54 | Frame Shift Del (DEL) | VAF 68/493 reads (14%) | called by pindel, varscan2*
- CABYR | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- CDH18 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- COL21A1 | c.961T>G p.L321V | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.15); called by muse, mutect2
- CYFIP2 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- EDN3 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHF | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- FCGR2C | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- FLG2 | c.1868C>A p.S623Y | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FRAS1 | c.8479G>T p.D2827Y | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FURIN | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK5 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- HSD3B2 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 63/563 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV1-17 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 45/602 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.165); called by muse, mutect2
- ITGB2 | c.815A>T p.D272V | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- KCNC3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- MFSD1 | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C11 | c.123G>C p.M41I | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- PLD5 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 29/409 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- PLXNB2 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- RGMA | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RHOT2 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL19 | c.422A>C p.H141P | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2
- SAMD9 | c.3982C>G p.Q1328E | Missense Mutation (SNP) | VAF 40/531 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.079); called by muse, mutect2
- SLC4A1AP | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SYNE1 | c.21743C>G p.S7248C (on ENST00000367255 / NM_182961.4; = p.S7177C on NM_033071.3) | Missense Mutation (SNP) | VAF 50/600 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- TAS2R3 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- TNRC6A | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TOX | c.1252C>G p.P418A | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- TP53 | c.574_581del p.Q192Yfs*14 | Frame Shift Del (DEL) | VAF 74/701 reads (11%) | called by mutect2, pindel
- TTN | c.88001C>G p.T29334R (on ENST00000591111; = p.T21910R on NM_003319.4) | Missense Mutation (SNP) | VAF 64/698 reads (9%) | PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF428 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCYL2 | c.249G>A p.A83= | Silent (SNP) | VAF 55/374 reads (15%) | called by muse, mutect2, varscan2
- ALDOA | c.498C>T p.G166= (on ENST00000642816 / NM_001243177.4; = p.G112= on NM_184041.5) | Silent (SNP) | VAF 119/789 reads (15%) | catalogued as rs145811469; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMS1 | c.906A>G p.V302= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- CDK11A | c.1305C>T p.G435= (on ENST00000378633 / NM_001313896.2; = p.G432= on NM_024011.4) | Silent (SNP) | VAF 21/404 reads (5%) | called by muse, mutect2
- CSMD3 | c.9126T>C p.S3042= (on ENST00000297405 / NM_001363185.1; = p.S2873= on NM_052900.3) | Silent (SNP) | VAF 38/618 reads (6%) | catalogued as COSV99824786; called by muse, mutect2
- CSN3 | c.273C>T p.A91= | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as rs1039355693; called by muse, mutect2, varscan2
- DACT1 | c.2061C>T p.Y687= | Silent (SNP) | VAF 120/361 reads (33%) | catalogued as rs1279029765; called by muse, mutect2, varscan2
- SEMA5B | c.2022G>A p.A674= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs778899118; called by muse, mutect2, varscan2
- SLC27A6 | c.1122T>A p.T374= | Silent (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- SNTB2 | c.1551T>C p.C517= | Silent (SNP) | VAF 10/169 reads (6%) | called by muse, mutect2
- STXBP2 | c.384G>A p.K128= | Silent (SNP) | VAF 63/477 reads (13%) | catalogued as rs750463059, COSV99657399; called by muse, mutect2, varscan2
- TBC1D2 | c.1218G>A p.L406= | Silent (SNP) | VAF 35/566 reads (6%) | called by muse, mutect2
- TMEM259 | c.1308C>G p.L436= | Silent (SNP) | VAF 30/418 reads (7%) | catalogued as rs368816689; called by muse, mutect2
- TRIM49B | c.24C>T p.V8= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- UNC79 | c.4938C>T p.D1646= (on ENST00000393151 / NM_001346218.2; = p.D1469= on NM_020818.5) | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as rs1383745877, COSV99828394; called by muse, mutect2
- CD37 | chr19:49332264 G>A | 5'Flank (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- GCKR | c.644+475C>T | Intron (SNP) | VAF 41/210 reads (20%) | called by muse, mutect2, varscan2
- KCNA5 | c.*13G>C | 3'UTR (SNP) | VAF 33/950 reads (3%) | called by muse, mutect2
- NOX4 | c.1516-31A>G | Intron (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2
- PCMTD1 | c.*2495G>C | 3'UTR (SNP) | VAF 32/554 reads (6%) | called by muse, mutect2
- SCYL2 | c.1642+431G>T | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
